Somatic mutation profile of tumor specimen MP2PRT-PASUMA-TMP1-A (aliquot MP2PRT-PASUMA-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASUMA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (925 days).
Specimen MP2PRT-PASUMA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 356e16c8-b45d-41e8-877a-52b14eabc996.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASUMA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASUMA-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11f0f959-0d47-48c9-93e7-70d2405054b6

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSRP3 | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 114/305 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as rs758947977, COSV99788427; called by muse, mutect2, varscan2
- KCNH3 | c.2995G>C p.D999H | Missense Mutation (SNP) | VAF 173/475 reads (36%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.455); catalogued as COSV57792899; called by muse, mutect2, varscan2
- EPHA5 | c.2174C>A p.A725E | Missense Mutation (SNP) | VAF 40/464 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2
- SP3 | c.2057G>A p.C686Y | Missense Mutation (SNP) | VAF 77/214 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ZDBF2 | c.611C>G p.T204R | Missense Mutation (SNP) | VAF 56/401 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- IGFN1 | c.3750C>T p.S1250= (on ENST00000295591 / NM_001367841.1; = p.S3707= on NM_001164586.2) | Silent (SNP) | VAF 35/482 reads (7%) | called by muse, mutect2
- ZNF804A | c.987C>T p.V329= | Silent (SNP) | VAF 112/254 reads (44%) | catalogued as rs774929418; called by muse, mutect2, varscan2
- DAPK2 | c.858+1689G>A | Intron (SNP) | VAF 74/338 reads (22%) | catalogued as rs756693345; called by muse, mutect2, varscan2
- IGHV3-53 | chr14:106592675 ins GGTGGA | 3'Flank (INS) | VAF 27/120 reads (23%) | called by pindel, varscan2
